Somatic mutation profile of tumor specimen ALCH-B4F6-TTP1-A (aliquot ALCH-B4F6-TTP1-A-1-0-D-A81V-36) from ALCHEMIST case ALCH-B4F6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 75.7 years (27,663 days).
Specimen ALCH-B4F6-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e3465b3-dca2-487f-8268-51ce273162c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4F6-NB1-A (Blood Derived Normal), aliquot ALCH-B4F6-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a5423dc-fa39-4876-bd02-f2714b65695f

The open-access MAF lists 81 somatic variants for this specimen: 55 protein-altering or splice-affecting, 16 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 16, Nonsense Mutation 4, RNA 4, Intron 3, 5'UTR 3, Splice Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCF1 | c.1195G>T p.G399* (on ENST00000326195 / NM_001025091.2; = p.G361* on NM_001090.3) | Nonsense Mutation (SNP) | VAF 7/150 reads (5%) | catalogued as COSV100401041; called by muse, mutect2
- ACTL7B | c.334G>T p.V112L | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV65927838; called by muse, mutect2
- ADAD1 | c.113G>C p.G38A | Missense Mutation (SNP) | VAF 9/227 reads (4%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV56647532; called by muse, mutect2
- ADGRL3 | c.726G>T p.W242C (on ENST00000506720 / NM_001322402.2; = p.W174C on NM_015236.6) | Missense Mutation (SNP) | VAF 20/421 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72268467; called by muse, mutect2
- ANK1 | c.2116C>T p.H706Y | Missense Mutation (SNP) | VAF 26/265 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as COSV55895849; called by muse, mutect2, varscan2
- BTNL3 | c.485A>C p.Q162P | Missense Mutation (SNP) | VAF 24/436 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.255); catalogued as rs1193050325; called by muse, mutect2
- CWC22 | c.1598A>G p.Y533C | Missense Mutation (SNP) | VAF 7/206 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1445489129; called by muse, mutect2
- FAM47C | c.2291C>A p.P764Q | Missense Mutation (SNP) | VAF 13/185 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as COSV63729705; called by muse, mutect2
- GATA3 | c.1109G>T p.S370I | Missense Mutation (SNP) | VAF 22/442 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV60517895; called by muse, mutect2
- KRT25 | c.988A>G p.T330A | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs768876904; called by muse, mutect2
- LDLRAD4 | c.275C>A p.S92Y | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV63344166; called by muse, mutect2
- MRC1 | c.2917G>T p.A973S | Missense Mutation (SNP) | VAF 24/775 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as rs1226082633; called by muse, mutect2
- MRPS35 | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 13/257 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.635); catalogued as COSV99317587; called by muse, mutect2
- PDZRN4 | c.2165A>T p.D722V (on ENST00000402685 / NM_001164595.2; = p.D464V on NM_013377.4) | Missense Mutation (SNP) | VAF 16/444 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.24); catalogued as rs1306919779, COSV54202639; called by muse, mutect2
- PHKB | c.1591C>T p.Q531* | Nonsense Mutation (SNP) | VAF 20/689 reads (3%) | catalogued as rs1473832602; called by muse, mutect2
- RLIM | c.1376C>T p.S459L | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as rs774103461; called by muse, mutect2, varscan2
- STAP1 | c.643A>G p.I215V | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.306); catalogued as rs1183202563; called by muse, mutect2
- TCHH | c.4157A>T p.Q1386L | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as COSV64272378; called by muse, mutect2
- WDFY4 | c.3988G>A p.V1330M | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1373950111, COSV100300574, COSV57435037; called by muse, mutect2
- ZNF444 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1467003669; called by muse, mutect2
- ZNF90 | c.551A>G p.Q184R | Missense Mutation (SNP) | VAF 80/346 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.034); catalogued as rs1555705903; called by muse, mutect2, varscan2
- ADGB | c.3400A>G p.T1134A | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, mutect2
- COL25A1 | c.1517G>T p.G506V | Missense Mutation (SNP) | VAF 14/403 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DLK1 | c.297C>A p.N99K | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.34); called by muse, mutect2
- DSEL | c.2957G>A p.G986D | Missense Mutation (SNP) | VAF 19/472 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.789); called by muse, mutect2
- ERICH3 | c.2867C>A p.T956K | Missense Mutation (SNP) | VAF 13/285 reads (5%) | SIFT tolerated (0.99); PolyPhen benign (0.005); called by muse, mutect2
- EVI5L | c.1444C>G p.Q482E | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); called by muse, mutect2
- EYS | c.4859C>G p.S1620* | Nonsense Mutation (SNP) | VAF 16/635 reads (3%) | called by muse, mutect2
- FAM47C | c.2290C>A p.P764T | Missense Mutation (SNP) | VAF 13/189 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.07); called by muse, mutect2
- LDHC | c.802A>T p.R268W | Missense Mutation (SNP) | VAF 22/462 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2
- MAGT1 | c.273-1G>T p.X91_splice (on ENST00000618282 / NM_001367916.1; = p.X123_splice on NM_032121.5) | Splice Site (SNP) | VAF 15/204 reads (7%) | called by muse, mutect2
- MASP2 | c.1264A>T p.K422* | Nonsense Mutation (SNP) | VAF 18/279 reads (6%) | called by muse, mutect2
- METTL5 | c.71T>C p.L24P | Missense Mutation (SNP) | VAF 7/194 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.009); called by muse, mutect2
- MRC1 | c.2918C>T p.A973V | Missense Mutation (SNP) | VAF 22/770 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); called by muse, mutect2
- MROH2B | c.4612C>A p.Q1538K | Missense Mutation (SNP) | VAF 7/190 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.022); called by muse, mutect2
- MROH2B | c.4611C>A p.S1537R | Missense Mutation (SNP) | VAF 7/188 reads (4%) | SIFT tolerated (0.55); PolyPhen benign (0.054); called by muse, mutect2
- MYO5A | c.4639A>G p.R1547G | Missense Mutation (SNP) | VAF 23/623 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.313); called by muse, mutect2
- NF1 | c.2079G>T p.M693I | Missense Mutation (SNP) | VAF 24/470 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2
- NPHS1 | c.877C>A p.H293N | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.275); called by muse, mutect2
- OR52H1 | c.210G>T p.M70I (on ENST00000322653; = p.M76I on NM_001005289.1) | Missense Mutation (SNP) | VAF 11/302 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- PCDHA10 | c.268G>C p.D90H | Missense Mutation (SNP) | VAF 38/436 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PSEN1 | c.1153G>T p.D385Y | Missense Mutation (SNP) | VAF 22/552 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RIMS2 | c.2263C>T p.P755S (on ENST00000666250 / NM_001348490.2; = p.P563S on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/356 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- RUNX1 | c.1154G>A p.G385D (on ENST00000344691 / NM_001001890.3; = p.G412D on NM_001754.5) | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2
- SELL | c.280C>G p.P94A (on ENST00000650983; = p.P81A on NM_000655.5) | Missense Mutation (SNP) | VAF 17/544 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SLC28A1 | c.1514C>T p.S505F | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- SPAG9 | c.1733A>C p.Y578S (on ENST00000262013 / NM_001130528.3; = p.Y564S on NM_003971.6) | Missense Mutation (SNP) | VAF 26/413 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); called by muse, mutect2
- STAB1 | c.1558dup p.S520Kfs*4 | Frame Shift Ins (INS) | VAF 7/65 reads (11%) | called by mutect2, pindel, varscan2
- STK38L | c.1259T>C p.L420S | Missense Mutation (SNP) | VAF 13/388 reads (3%) | SIFT tolerated (0.62); PolyPhen benign (0.038); called by muse, mutect2
- TEX15 | c.2422C>A p.P808T (on ENST00000256246; = p.P1191T on NM_001350162.2) | Missense Mutation (SNP) | VAF 34/499 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.027); called by muse, mutect2
- TEX15 | c.948G>T p.K316N (on ENST00000256246; = p.K699N on NM_001350162.2) | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TG | c.4528+1G>C p.X1510_splice | Splice Site (SNP) | VAF 11/316 reads (3%) | called by muse, mutect2
- TLL1 | c.362G>C p.G121A | Missense Mutation (SNP) | VAF 22/590 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.197); called by muse, mutect2
- UBR7 | c.968A>T p.Y323F | Missense Mutation (SNP) | VAF 21/300 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); called by muse, mutect2
- ZSCAN4 | c.367A>T p.T123S | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ADAM18 | c.1284A>T p.S428= | Silent (SNP) | VAF 27/448 reads (6%) | called by muse, mutect2
- ADAMTS16 | c.3177C>A p.A1059= | Silent (SNP) | VAF 6/110 reads (5%) | called by muse, mutect2
- ANK1 | c.628C>T p.L210= | Silent (SNP) | VAF 12/253 reads (5%) | called by muse, mutect2
- DNAH3 | c.5394T>C p.A1798= | Silent (SNP) | VAF 15/300 reads (5%) | called by muse, mutect2
- IVL | c.1050G>A p.E350= | Silent (SNP) | VAF 14/183 reads (8%) | catalogued as rs972907388; called by muse, mutect2
- KDM5B | c.1800T>C p.V600= | Silent (SNP) | VAF 16/345 reads (5%) | called by muse, mutect2
- MKLN1 | c.811A>C p.R271= | Silent (SNP) | VAF 23/358 reads (6%) | called by muse, mutect2
- PCDHA5 | c.594C>A p.S198= | Silent (SNP) | VAF 15/327 reads (5%) | called by muse, mutect2
- PRDM13 | c.903G>A p.A301= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as rs1355780412; called by muse, mutect2
- RNF34 | c.447C>T p.C149= | Silent (SNP) | VAF 12/328 reads (4%) | called by muse, mutect2
- SAR1A | c.63G>T p.L21= | Silent (SNP) | VAF 14/256 reads (5%) | called by muse, mutect2
- SYNE1 | c.5721G>A p.K1907= (on ENST00000367255 / NM_182961.4; = p.K1914= on NM_033071.3) | Silent (SNP) | VAF 36/788 reads (5%) | catalogued as COSV54987592; called by muse, mutect2
- TBX2 | c.1446G>A p.P482= | Silent (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- TNNI3K | c.1956T>A p.A652= | Silent (SNP) | VAF 24/442 reads (5%) | called by muse, mutect2
- WDFY4 | c.2076G>T p.L692= | Silent (SNP) | VAF 12/175 reads (7%) | called by muse, mutect2
- XKR3 | c.939A>G p.L313= | Silent (SNP) | VAF 8/196 reads (4%) | catalogued as rs1267420306; called by muse, mutect2
- ASXL1 | c.57+451C>A | Intron (SNP) | VAF 15/171 reads (9%) | called by muse, mutect2
- CPNE1 | c.1050+73A>G | Intron (SNP) | VAF 8/168 reads (5%) | called by muse, mutect2
- DNM1P47 | n.704G>T | RNA (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2
- NIBAN1 | c.-45C>G | 5'UTR (SNP) | VAF 8/188 reads (4%) | called by muse, mutect2
- OR1F2P | n.298A>T | RNA (SNP) | VAF 20/296 reads (7%) | called by muse, mutect2
- OR2L1P | n.351A>T | RNA (SNP) | VAF 12/338 reads (4%) | called by muse, mutect2
- OTUD6B | c.-13G>A | 5'UTR (SNP) | VAF 24/460 reads (5%) | called by muse, mutect2
- TIMD4 | c.-11C>G | 5'UTR (SNP) | VAF 9/243 reads (4%) | catalogued as COSV99192520; called by muse, mutect2
- TMEM51 | c.-267+14741T>C | Intron (SNP) | VAF 30/264 reads (11%) | called by muse, mutect2, varscan2
- TUBB7P | n.492A>G | RNA (SNP) | VAF 19/137 reads (14%) | catalogued as rs782314552; called by muse, varscan2
